Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A4F2, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A4F2-06A (Metastatic).

Patient: Xxxx

Translation of pathology report

Sample

1CD-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous tissue, NOS
(pw TSS) c49.9

Gross Pathology

Cryofixed specimen with a weight of 91 mg.

hw
10/7/12

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 85 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine.

Some apoptotic cells are present.

There is a high nucleo/cytoplasmatic ratio. The mitotic count is 5 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm.

The tumor shows a growth pattern with nest formation.

Lymphocytic infiltrates compound approx. 3 percent of the tissue cells.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

hw
9/11/12

Source: NCI Genomic Data Commons file 414c5112-6aa9-496e-b816-9f98d6231de5 (TCGA-FS-A4F2.DE510F4B-B8C8-44AA-8470-736E6B027E2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).